Somatic mutation profile of tumor specimen ASCProject_0102_T2_WES (aliquot ASCProject_0102_T2_WES_1) from CMI case ASCProject_0102, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 31.8 years (11,632 days).
Specimen ASCProject_0102_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70f47a63-31f5-4926-9fcc-f08953f40a90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0102_SALIVA (Saliva), aliquot ASCProject_0102_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89fdf259-324e-4c9c-b754-f63d8e479f19

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 15, Silent 9, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP100 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs151214306; called by muse, mutect2, varscan2
- DMD | c.287G>C p.S96T | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV99926392; called by muse, varscan2
- ITGA2B | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.151); catalogued as rs1268718358; called by muse, mutect2, varscan2
- KCNIP2 | c.662G>T p.R221L (on ENST00000356640 / NM_173191.3; = p.R236L on NM_014591.5) | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs149050202; called by muse, mutect2, varscan2
- PLCG1 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54814695; called by muse, mutect2, varscan2
- SULF1 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758690728, COSV52674097; called by muse, mutect2, varscan2
- TNR | c.94C>A p.Q32K | Missense Mutation (SNP) | VAF 77/302 reads (25%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV99688631; called by muse, mutect2, varscan2
- CDH26 | c.1706G>T p.R569L | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FKRP | c.118C>G p.R40G | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- H3C7 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 24/662 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- PIP4P2 | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- RARA | c.630+1G>C p.X210_splice | Splice Site (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- RITA1 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOS2 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNXB | c.9971G>C p.S3324T (on ENST00000647633; = p.S3077T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZNF799 | c.539C>G p.S180C | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- ABCC5 | c.3729G>T p.L1243= | Silent (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- BRINP3 | c.132C>T p.F44= | Silent (SNP) | VAF 72/382 reads (19%) | catalogued as rs759445587, COSV66541011; called by muse, mutect2, varscan2
- FCGR3A | c.36T>G p.L12= | Silent (SNP) | VAF 26/159 reads (16%) | called by muse, mutect2, varscan2
- GNB4 | c.63T>G p.A21= | Silent (SNP) | VAF 45/196 reads (23%) | called by muse, mutect2, varscan2
- GPR179 | c.1767C>T p.S589= (on ENST00000621958; = p.S588= on NM_001004334.4) | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as rs764035734; called by muse, mutect2, varscan2
- KCNK2 | c.1215C>A p.I405= (on ENST00000444842 / NM_001017425.3; = p.I390= on NM_014217.4) | Silent (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- LRFN3 | c.169C>T p.L57= | Silent (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- RHEBL1 | c.210G>T p.L70= | Silent (SNP) | VAF 25/154 reads (16%) | called by muse, mutect2, varscan2
- TFAP2D | c.1260G>A p.A420= | Silent (SNP) | VAF 86/460 reads (19%) | catalogued as rs770586423, COSV50449188; called by muse, mutect2, varscan2
